CPTAC case 11LU035 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba0fe300-d3f0-42fd-b609-3ee3d0e49d7b

Demographics
Sex at birth: male; Race: asian; Year of birth: 1956; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 59.3 years (21,677 days); Year of diagnosis: 2015; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Tumor grade: GX; Residual disease: R0; Days to last known disease status: 7 days; Days to last follow up: 7 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 3; Margin status: Uninvolved.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 7.

Other clinical attributes
- Weight: 57 kg; Height: 168 cm; BMI: 20.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 5; Cigarettes per day: 5; Tobacco smoking onset year: 1995; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 27.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample 2f2e5477-42a4-4906-a943-bf7f80: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 300 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide 2f2e5477-42a4-4906-a943-bf7f80_D1_D1: Section location: not specified; Percent tumor nuclei: 70; Percent necrosis: 5.
- Sample 6b328a7b-2d97-4a02-8a6c-89f96a: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Method of sample procurement: Blood Draw.
